Gene-level copy-number profile of specimen HCM-WCMC-0951-C67-85A from HCMI case HCM-WCMC-0951-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0951-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f30c05e4-26a1-4994-b230-3a0818b9ed54.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0951-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/684ee3ce-7233-4e59-8323-23ce009c9032

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 8,452; copy number 2: 46,216; copy number 3: 3,396; copy number 4: 313.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:12,330,885–12,571,392, 7 genes (within-gene range 0–1): VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1.
- chr11:528,907–706,715, 15 genes (within-gene range 0–2): AC137894.1, HRAS, LRRC56, LMNTD2, LMNTD2-AS1, RASSF7, MIR210HG, MIR210, PHRF1, IRF7, CDHR5, SCT, DRD4, DEAF1, AC131934.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,410. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
